Gene-level copy-number profile of tumor specimen TCGA-A2-A0YK-01A from TCGA case TCGA-A2-A0YK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.9 years (22,625 days).
Specimen TCGA-A2-A0YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8536ff4e-4027-4673-96b9-43f4f61a5376.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0YK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/08034f1f-dfba-48bb-abb0-c5b3d6d99191

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,919; copy number 3: 265; copy number 4: 48,707; copy number 6: 2,604; copy number 8: 4; copy number 11: 51; copy number 12: 12; copy number 14: 163; copy number 15: 24; copy number 19: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0YK-01A-22D-A107-01): tumor purity 0.4, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 321 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,604,856–34,039,104, 7 genes, copy number 14 (within-gene range 2–14): AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4.
- chr8:34,784,028–39,580,134, 95 genes, copy number 15–19 (within-gene range 4–19) (broad region; genes not listed).
- chr11:66,312,853–68,213,828, 118 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).
- chr11:68,754,620–72,005,715, 100 genes, copy number 11–14 (broad region; genes not listed).
- chr11:72,014,291–72,020,910, 1 gene, copy number 12 (within-gene range 12–18): AP002490.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
